Somatic mutation profile of tumor specimen MP2PRT-PASPAP-TMP1-A (aliquot MP2PRT-PASPAP-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASPAP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,165 days).
Specimen MP2PRT-PASPAP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 343c75df-683b-4d2b-bc29-9434e7e1d28f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASPAP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASPAP-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a6836b2-8219-4e60-82be-427ff89c561f

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAT5B | c.1924A>C p.N642H | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as rs938448224, COSV53180204; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- IKZF1 | c.1520C>T p.S507L | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58784013, COSV58793145; called by muse, mutect2, varscan2
- OBSCN | c.8368C>T p.R2790* | Nonsense Mutation (SNP) | VAF 32/458 reads (7%) | catalogued as rs781773904; called by muse, mutect2
- OBSL1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 21/740 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54718125; called by muse, mutect2
- PDZRN3 | c.2815C>T p.R939W | Missense Mutation (SNP) | VAF 21/551 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1167796545, COSV55206764; called by muse, mutect2
- PRR32 | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64420548; called by muse, mutect2, varscan2
- STON2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 89/430 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1404525096, COSV50845595; called by muse, mutect2, varscan2
- TRPV3 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 71/219 reads (32%) | catalogued as rs765435661, COSV56790065; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, mutect2, varscan2
- ADAM19 | c.2498G>T p.R833M | Missense Mutation (SNP) | VAF 17/420 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2
- MAGED2 | c.1362G>T p.M454I | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SH2B3 | c.1343T>A p.L448H | Missense Mutation (SNP) | VAF 147/393 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA1 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.298); called by muse, mutect2
- KLF9 | c.186C>G p.T62= | Silent (SNP) | VAF 96/452 reads (21%) | called by muse, mutect2, varscan2
- PHLDA1 | c.606A>G p.Q202= | Silent (SNP) | VAF 46/411 reads (11%) | catalogued as rs775747072, COSV56997985; called by muse, mutect2, varscan2
- SHROOM4 | c.315G>A p.K105= | Silent (SNP) | VAF 17/376 reads (5%) | called by muse, mutect2
- SLC22A17 | n.1562G>A | RNA (SNP) | VAF 54/262 reads (21%) | catalogued as rs955299617; called by muse, mutect2, varscan2
